Somatic mutation profile of tumor specimen TARGET-10-PARWLP-09A (aliquot TARGET-10-PARWLP-09A-01D) from TARGET case TARGET-10-PARWLP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,884 days).
Specimen TARGET-10-PARWLP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d4ac348-ea54-4b79-806a-7fdabae53153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARWLP-10A (Blood Derived Normal), aliquot TARGET-10-PARWLP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80f779c3-ce2d-4a0e-a3d5-1fb46b2af509

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 3, Intron 3, Frame Shift Del 1, Splice Site 1, 3'UTR 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.722_723insAGCC p.F241Lfs*3 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as CI067254, CI983202, COSV64295304, COSV99058019; called by pindel, varscan2
- VWA8 | c.4424delinsGG p.S1475Wfs*19 | Frame Shift Ins (INS) | VAF 13/87 reads (15%) | catalogued as COSV101022577; called by mutect2*, pindel, varscan2*
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 3/30 reads (10%) | called by pindel, varscan2*
- VAMP3 | c.172del p.S58Lfs*10 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- VWA8 | c.4425dup p.P1476Afs*18 | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | called by mutect2, varscan2
- ZNF518A | c.1305A>G p.A435= | Silent (SNP) | VAF 116/192 reads (60%) | called by muse, mutect2, varscan2
- CFAP298 | c.763-101C>G | Intron (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- ERN2 | c.307-91T>G | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- GNG7 | c.-38+16998A>G | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- HECTD1 | c.-3dup | 5'UTR (INS) | VAF 14/129 reads (11%) | catalogued as rs1207761225; called by mutect2, pindel, varscan2
- HLA-DMB | c.*183T>C | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
